Gene-level copy-number profile of tumor specimen C3N-02926-01 (profiled together with C3N-02926-02) from CPTAC case C3N-02926, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 50.5 years (18,463 days).
Specimen C3N-02926-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8def8a44-e9cc-4f8e-8076-375b724a1ae9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02926-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/90e2cd46-0b3f-4511-8de9-712ed486dede

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 330; copy number 2: 1,333; copy number 3: 10,492; copy number 4: 25,538; copy number 5: 8,915; copy number 6: 6,270; copy number 7: 331; copy number 8: 4,434; copy number 9: 663; copy number 10: 1; copy number 11: 64; copy number 13: 3; copy number 15: 2; copy number 20: 1; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr16:32,356,981–32,380,049, 2 genes: AC133548.1, ACTR3BP3.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr19:20,432,552–20,571,095, 2 genes (within-gene range 0–4): AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 735 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:86,649–11,243,715, 514 genes, copy number 9 (broad region; genes not listed).
- chr11:11,351,942–11,353,307, 2 genes, copy number 9 (within-gene range 7–9): CSNK2A3, AC023946.1.
- chr11:11,956,207–15,247,208, 55 genes, copy number 9–11 (within-gene range 7–11): DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC.
- chr11:41,518,895–48,170,841, 156 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr16:32,188,333–32,202,822, 3 genes, copy number 13: AC133485.5, AC133485.4, ABHD17AP8.
- chr16:32,439,069–32,441,159, 1 gene, copy number 10: PABPC1P13.
- chr16:32,475,051–32,615,639, 2 genes, copy number 20–24: ABCD1P3, AC137800.1.
- chr16:32,809,556–32,824,645, 2 genes, copy number 15: AC137761.1, AC137761.2.

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
